MMRF case MMRF_2397 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9a243d87-c972-41e0-9485-1c9196cb8e2e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.7 years (18,502 days); ISS stage: II; Days to last known disease status: 785 days (2.1 years); Days to last follow up: 785 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 99 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 165 days; Days to treatment end: 165 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 183 days; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 284 days; Days to treatment end: 343 days.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 343 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27 (ECOG 1): M Protein 3.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 5.22 g/L; Immunoglobulin A 50 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.69 µg/mL; Lactate Dehydrogenase 1.42 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 5.02 ×10⁹/L; Platelets 282 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 9.3 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 0.15 mg/dL.
- Day 43 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 6.51 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 0.71 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.61 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.08 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 165 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 6.83 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.17 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 6.05 mmol/L.
- Day 260: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.11 mg/dL; Immunoglobulin G 5.83 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.63 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.84 mmol/L.
- Day 295: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 6.21 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.34 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 421 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 5.34 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.37 µg/mL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 7.14 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 6.77 mmol/L.
- Day 505 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 5.84 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 1.3 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 6.14 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 5.39 mmol/L.
- Day 602 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 5.5 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.69 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 3.85 mmol/L.
- Day 715 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 4.83 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.38 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.54 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.28 mmol/L.
- Day 785 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 5.76 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.25 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 11.6 ×10⁹/L; Absolute Neutrophil 10.4 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -27: Weight: 76 kg; Height: 180 cm.

Biospecimens (2 samples)
- Sample MMRF_2397_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_2397_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
